MMRF case MMRF_2606 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cc8e53fa-84f3-487d-b2f3-15aa16e216e1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 70 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 70.1 years (25,590 days); ISS stage: II; Days to last known disease status: 617 days (1.7 years); Days to last follow up: 617 days (1.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 200 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 211 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 209 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 220 days; Days to treatment end: 227 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 221 days; Days to treatment end: 221 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 592 days (1.6 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 625 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 1): M Protein 0.41 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.13 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 224 mg/dL; Immunoglobulin G 7.7 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 5.02 µg/mL; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.77 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 216 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.4 mmol/L; Albumin 44.6 g/L; Total Protein 6.47 g/dL; Glucose 5.23 mmol/L; C-Reactive Protein 0.02 mg/dL.
- Day 80 (ECOG 1): M Protein 0.18 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 50.5 mg/dL; Immunoglobulin G 4.49 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.049 g/L; Beta 2 Microglobulin 2.66 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 2.81 ×10⁹/L; Absolute Neutrophil 1.81 ×10⁹/L; Platelets 221 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 1.36 mmol/L; Calcium 2.28 mmol/L; Albumin 40.3 g/L; Total Protein 5.57 g/dL; Glucose 4.4 mmol/L.
- Day 184 (ECOG 1): M Protein 0.17 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 54.7 mg/dL; Immunoglobulin G 3.96 g/L; Immunoglobulin A 0.069 g/L; Immunoglobulin M 0.049 g/L; Beta 2 Microglobulin 3.07 µg/mL; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.56 ×10⁹/L; Absolute Neutrophil 2.64 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 40.7 µmol/L; Blood Urea Nitrogen 1.5 mmol/L; Calcium 2.15 mmol/L; Albumin 43.6 g/L; Total Protein 6.14 g/dL; Glucose 5.12 mmol/L.
- Day 269 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 22 mg/dL; Immunoglobulin G 5.4 g/L; Immunoglobulin A 0.23 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 2.05 µg/mL; Lactate Dehydrogenase 2.98 µkat/L; Hemoglobin 6.45 mmol/L; Leukocytes 3.29 ×10⁹/L; Absolute Neutrophil 1.79 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 46.9 µmol/L; Blood Urea Nitrogen 1 mmol/L; Calcium 2.28 mmol/L; Albumin 42.3 g/L; Total Protein 5.8 g/dL; Glucose 4.51 mmol/L.
- Day 353 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.29 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 36.8 mg/dL; Immunoglobulin G 6.05 g/L; Immunoglobulin A 0.1 g/L; Immunoglobulin M 0.049 g/L; Beta 2 Microglobulin 2.59 µg/mL; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 2.83 ×10⁹/L; Absolute Neutrophil 1.66 ×10⁹/L; Platelets 174 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 1.43 mmol/L; Calcium 2.48 mmol/L; Albumin 45.4 g/L; Total Protein 6.1 g/dL; Glucose 4.29 mmol/L.
- Day 458 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 66.5 mg/dL; Immunoglobulin G 5.28 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 3.05 ×10⁹/L; Absolute Neutrophil 1.56 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 53.9 µmol/L; Blood Urea Nitrogen 1.57 mmol/L; Calcium 2.23 mmol/L; Albumin 46.4 g/L; Total Protein 6.09 g/dL; Glucose 4.57 mmol/L.
- Day 549 (ECOG 0): M Protein 0.15 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.22 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 130 mg/dL; Immunoglobulin G 4 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.13 µg/mL; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 3.67 ×10⁹/L; Absolute Neutrophil 2.27 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 49.5 µmol/L; Blood Urea Nitrogen 1.18 mmol/L; Calcium 2.28 mmol/L; Albumin 48.4 g/L; Total Protein 6.45 g/dL; Glucose 4.84 mmol/L.
- Day 617 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 19.3 mg/dL; Immunoglobulin G 4.13 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 2.6 µg/mL; Lactate Dehydrogenase 1.8 µkat/L; Hemoglobin 5.87 mmol/L; Leukocytes 2.02 ×10⁹/L; Absolute Neutrophil 0.98 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 53 µmol/L; Calcium 2.13 mmol/L; Total Protein 5.06 g/dL; Glucose 4.46 mmol/L.

Other clinical attributes
- Day -2: Weight: 59 kg; Height: 148 cm.

Biospecimens (2 samples)
- Sample MMRF_2606_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_2606_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
